CCDI case PBBXBL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4c352ad7-15e3-4aee-ba8f-0c8aeaeae83d

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.2 years (3,714 days).

Biospecimens (3 samples)
- Sample 0DJHE3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJHEL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJHH8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
